Somatic mutation profile of tumor specimen TCGA-W2-A7HD-01A (aliquot TCGA-W2-A7HD-01A-11D-A35I-08) from TCGA case TCGA-W2-A7HD, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 76.6 years (27,962 days).
Specimen TCGA-W2-A7HD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6ea2d2d-085a-4a39-974f-95f4dd69ba2f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W2-A7HD-10D (Blood Derived Normal), aliquot TCGA-W2-A7HD-10D-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42a8a194-533d-4493-b63e-6239725ec2d4

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 10, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 32/66 reads (48%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AHNAK | c.4440A>G p.I1480M | Missense Mutation (SNP) | VAF 94/216 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs1259579417; called by muse, mutect2, varscan2
- DMBT1 | c.7573G>A p.V2525I (on ENST00000338354 / NM_001377530.1; = p.V1768I on NM_004406.3) | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.066); catalogued as rs755743749, COSV57541855; called by muse, mutect2, varscan2
- MARK2 | c.1205A>G p.N402S | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as COSV59289932; called by muse, mutect2, varscan2
- METTL21A | c.203C>G p.S68C | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.552); catalogued as rs374199210, COSV55881665; called by muse, mutect2, varscan2
- PHC3 | c.911C>A p.S304Y (on ENST00000494943 / NM_001308116.2; = p.S316Y on NM_024947.4) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV71948187; called by muse, mutect2, varscan2
- DPP6 | c.2516T>C p.I839T (on ENST00000377770 / NM_001364500.2; = p.I777T on NM_001936.5) | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- SCGB3A2 | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.081); called by muse, mutect2
- TMEM126B | c.127C>G p.L43V | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- USP28 | c.1013A>G p.D338G | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- RUFY1 | c.690T>C p.N230= | Silent (SNP) | VAF 19/43 reads (44%) | called by muse, mutect2, varscan2
- SYNE1 | c.18630C>T p.P6210= (on ENST00000367255 / NM_182961.4; = p.P6139= on NM_033071.3) | Silent (SNP) | VAF 30/78 reads (38%) | catalogued as rs1022996215, COSV99563462; called by muse, mutect2, varscan2
